Gene-level copy-number profile of tumor specimen C3N-02262-02 from CPTAC case C3N-02262, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.3 years (24,568 days).
Specimen C3N-02262-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4fefeaca-fc3b-4e8d-b1e8-bf8b8bdb025f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02262-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/0bcba063-b061-4684-9dba-e8135948c066

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 392; copy number 2: 12,029; copy number 3: 14,497; copy number 4: 21,732; copy number 5: 5,580; copy number 6: 3,389; copy number 8: 1,291.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:79,957,566–79,958,142, 1 gene: HMGB1P38.
- chr16:7,004,007–7,126,639, 2 genes (within-gene range 0–5): RNU6-328P, AC022206.1.
- chr18:1,927,727–1,929,094, 1 gene (within-gene range 0–2): AIDAP3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 387. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
